Somatic mutation profile of tumor specimen C3N-02337-02 (aliquot CPT0136280006) from CPTAC case C3N-02337, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 69.9 years (25,527 days).
Specimen C3N-02337-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66285724-8619-4308-bb38-8cc79acf998e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02337-71 (Blood Derived Normal), aliquot CPT0136390002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04d6061d-c5a8-49a2-a855-54ff7219ad84

The open-access MAF lists 80 somatic variants for this specimen: 58 protein-altering or splice-affecting, 17 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 17, Nonsense Mutation 5, Frame Shift Del 4, Splice Site 3, 5'UTR 2, 3'UTR 2, Frame Shift Ins 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 64/350 reads (18%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 48/104 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- PCSK1 | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 99/296 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137852824, CM074404; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1746-2A>T p.X582_splice (on ENST00000521381 / NM_181523.3; = p.X312_splice on NM_181504.4) | Splice Site (SNP) | VAF 73/199 reads (37%) | hotspot (GDC flag); catalogued as COSV57125460, COSV57131831, COSV57142185; called by muse, mutect2, varscan2
- ADGRG4 | c.7355del p.P2452Lfs*12 | Frame Shift Del (DEL) | VAF 69/241 reads (29%) | catalogued as COSV54956055; called by mutect2, pindel, varscan2
- ARID1A | c.656G>T p.R219L | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs1450841040; called by muse, mutect2, varscan2
- BAIAP3 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 56/199 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs142556073; called by muse, mutect2, varscan2
- CENPF | c.6551T>C p.V2184A | Missense Mutation (SNP) | VAF 58/337 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.024); catalogued as rs770701600; called by muse, mutect2, varscan2
- CHD4 | c.3446G>A p.R1149Q (on ENST00000357008 / NM_001363606.2; = p.R1162Q on NM_001273.5) | Missense Mutation (SNP) | VAF 58/194 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58903721; called by muse, mutect2, varscan2
- DAAM2 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 55/172 reads (32%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.508); catalogued as rs776862321, COSV51329286; called by muse, mutect2, varscan2
- DNM2 | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 117/344 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs762179685; called by muse, mutect2, varscan2
- DTNA | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 100/357 reads (28%) | catalogued as COSV51991551; called by muse, mutect2, varscan2
- GDF15 | c.616G>C p.G206R | Missense Mutation (SNP) | VAF 110/269 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs749868105; called by muse, mutect2, varscan2
- GGCT | c.390C>G p.Y130* | Nonsense Mutation (SNP) | VAF 49/146 reads (34%) | catalogued as COSV50040717, COSV50040973; called by muse, mutect2
- GTDC1 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs114650281; called by muse, mutect2, varscan2
- HNRNPM | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 93/426 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as rs185304866; called by muse, mutect2, varscan2
- MAS1 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 82/242 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs747248947; called by muse, mutect2, varscan2
- NRXN2 | c.3664G>A p.D1222N | Missense Mutation (SNP) | VAF 101/312 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55450970; called by muse, mutect2, varscan2
- NSMAF | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as rs367758314; called by muse, mutect2, varscan2
- OR4K15 | c.233G>A p.R78H (on ENST00000305051; = p.R54H on NM_001005486.1) | Missense Mutation (SNP) | VAF 64/175 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs202109557; called by muse, mutect2
- PBX3 | c.937G>A p.V313M | Missense Mutation (SNP) | VAF 47/238 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.479); catalogued as rs771847017; called by muse, mutect2, varscan2
- PCDHGB3 | c.1547C>T p.A516V | Missense Mutation (SNP) | VAF 168/531 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs781345070, COSV53933204; called by muse, mutect2, varscan2
- PIK3R1 | c.1700A>C p.K567T (on ENST00000521381 / NM_181523.3; = p.K297T on NM_181504.4) | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV104387195; called by muse, mutect2, varscan2
- PLP1 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 155/479 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58275871; called by muse, mutect2, varscan2
- PRKCZ | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.342); catalogued as rs761837545; called by muse, mutect2, varscan2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 103/241 reads (43%) | catalogued as rs146650273; called by pindel, varscan2
- RBM12B | c.2005C>T p.R669W | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.451); catalogued as rs761795060, COSV67897852; called by muse, mutect2, varscan2
- RSRP1 | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 51/187 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.171); catalogued as rs775912262; called by muse, mutect2, varscan2
- SCAF4 | c.1276C>T p.R426* | Nonsense Mutation (SNP) | VAF 10/80 reads (13%) | catalogued as rs924159079, COSV54586260; called by muse, mutect2, varscan2
- SIX2 | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 122/350 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.572); catalogued as rs929368932, COSV57390036; called by muse, mutect2, varscan2
- SLC10A4 | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 56/200 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.013); catalogued as rs746027527, COSV99906795; called by muse, mutect2, varscan2
- TPST2 | c.37G>A p.G13S | Missense Mutation (SNP) | VAF 133/395 reads (34%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.015); catalogued as rs758137775; called by muse, mutect2, varscan2
- TRA2B | c.560G>T p.R187L | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV52026125; called by muse, mutect2, varscan2
- TWIST1 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 127/362 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as rs776280385; called by muse, mutect2, varscan2
- ABCC12 | c.1276C>T p.Q426* | Nonsense Mutation (SNP) | VAF 78/227 reads (34%) | called by muse, mutect2, varscan2
- AFF4 | c.971C>G p.T324R | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ARID1A | c.1703del p.P568Qfs*51 | Frame Shift Del (DEL) | VAF 115/402 reads (29%) | called by mutect2, pindel, varscan2
- ASB9 | c.325G>T p.A109S | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- BCLAF1 | c.2425A>G p.R809G | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- CAMTA1 | c.4476dup p.A1493Rfs*13 | Frame Shift Ins (INS) | VAF 65/437 reads (15%) | called by mutect2, pindel, varscan2
- CHD1L | c.1206_1210del p.R402Sfs*4 | Frame Shift Del (DEL) | VAF 30/272 reads (11%) | called by mutect2, pindel
- COL28A1 | c.335A>G p.K112R | Missense Mutation (SNP) | VAF 65/210 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DNAJB7 | c.361A>G p.N121D | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- EIF4B | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ENOX2 | c.183T>C p.P61= (on ENST00000338144 / NM_001382520.1; = p.P32= on NM_006375.3 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 26/70 reads (37%) | called by mutect2, varscan2
- FOXE1 | c.952G>A p.V318M | Missense Mutation (SNP) | VAF 145/418 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- HEMGN | c.1267T>C p.F423L | Missense Mutation (SNP) | VAF 130/385 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MAST1 | c.4430G>A p.R1477Q | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MED26 | c.1357C>G p.Q453E | Missense Mutation (SNP) | VAF 74/244 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MYO1D | c.2000G>A p.G667D | Missense Mutation (SNP) | VAF 121/425 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PAX6 | c.530G>T p.C177F | Missense Mutation (SNP) | VAF 59/230 reads (26%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- PDZD11 | c.388+1G>A p.X130_splice | Splice Site (SNP) | VAF 82/226 reads (36%) | called by muse, mutect2, varscan2
- PIEZO1 | c.1100C>A p.S367Y | Missense Mutation (SNP) | VAF 113/313 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RCOR3 | c.1094A>G p.K365R | Missense Mutation (SNP) | VAF 17/560 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.028); called by muse, mutect2
- TPP2 | c.1777A>G p.R593G | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- UNC80 | c.4897T>G p.F1633V | Missense Mutation (SNP) | VAF 70/211 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- USP9X | c.3978-1G>A p.X1326_splice | Splice Site (SNP) | VAF 8/180 reads (4%) | called by muse, mutect2
- ZFYVE26 | c.1011G>T p.Q337H | Missense Mutation (SNP) | VAF 91/349 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- CNIH3 | c.246C>T p.F82= | Silent (SNP) | VAF 51/262 reads (19%) | called by muse, mutect2, varscan2
- COL7A1 | c.1911G>A p.P637= | Silent (SNP) | VAF 126/463 reads (27%) | catalogued as rs1211687404; called by muse, mutect2, varscan2
- CSMD3 | c.8607C>A p.S2869= (on ENST00000297405 / NM_001363185.1; = p.S2700= on NM_052900.3) | Silent (SNP) | VAF 77/235 reads (33%) | catalogued as COSV52159949; called by muse, mutect2, varscan2
- DLGAP4 | c.198G>A p.P66= | Silent (SNP) | VAF 83/221 reads (38%) | catalogued as rs777239234, COSV59414565, COSV59423956; called by muse, mutect2, varscan2
- FAM9B | c.345C>T p.D115= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as rs150312431, COSV59120612; called by muse, mutect2, varscan2
- HYDIN | c.12087C>T p.C4029= | Silent (SNP) | VAF 53/204 reads (26%) | called by muse, mutect2, varscan2
- MOCS1 | c.1680C>T p.S560= | Silent (SNP) | VAF 95/298 reads (32%) | called by muse, mutect2, varscan2
- MYH6 | c.2865C>T p.D955= | Silent (SNP) | VAF 152/537 reads (28%) | called by muse, mutect2, varscan2
- NAV1 | c.633A>G p.Q211= | Silent (SNP) | VAF 73/472 reads (15%) | called by muse, mutect2, varscan2
- NRXN1 | c.84C>A p.G28= | Silent (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- PCDHA8 | c.1614C>T p.R538= | Silent (SNP) | VAF 338/980 reads (34%) | catalogued as rs1329962165, COSV65323304; called by muse, mutect2, varscan2
- TNXB | c.8226C>T p.G2742= (on ENST00000647633; = p.G2495= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/98 reads (36%) | catalogued as rs770080446, COSV64483250; called by muse, mutect2, varscan2
- TRIM54 | c.27G>A p.P9= | Silent (SNP) | VAF 35/111 reads (32%) | catalogued as rs372346323; called by muse, mutect2, varscan2
- TRPM4 | c.1647G>T p.S549= | Silent (SNP) | VAF 184/431 reads (43%) | called by muse, mutect2, varscan2
- UNCX | c.579G>A p.A193= | Silent (SNP) | VAF 220/586 reads (38%) | catalogued as rs375923495; called by muse, mutect2, varscan2
- ZNF488 | c.883C>A p.R295= | Silent (SNP) | VAF 161/367 reads (44%) | called by muse, mutect2, varscan2
- ZNF628 | c.480G>A p.S160= | Silent (SNP) | VAF 98/340 reads (29%) | called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.-40G>A | 5'UTR (SNP) | VAF 35/86 reads (41%) | catalogued as rs1188043988; called by muse, mutect2, varscan2
- FAM185A | c.-67G>A | 5'UTR (SNP) | VAF 62/240 reads (26%) | catalogued as COSV68644470; called by muse, mutect2, varscan2
- KIAA0513 | c.*5C>T | 3'UTR (SNP) | VAF 38/136 reads (28%) | catalogued as rs779231870; called by muse, mutect2, varscan2
- MGST3 | c.250-33C>A | Intron (SNP) | VAF 111/513 reads (22%) | catalogued as rs376203864; called by muse, mutect2, varscan2
- UNC5D | c.*2391G>C | 3'UTR (SNP) | VAF 34/71 reads (48%) | called by muse, mutect2, varscan2
